Surgical pathology report (de-identified scan), TCGA case TCGA-06-0879, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0879-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

06-0879

CLINICAL HISTORY

Not Given

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Brain, excision biopsy

PATHOLOGICAL DIAGNOSIS:

Brain, site unspecified, excision: Glioblastoma (WHO Grade IV).

COMMENT

The Ki-67 labeling index is approximately 20%.

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing performed on tissue block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

[page 2 of 2]
[REDACTED]

determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

A. Brain, excision biopsy: High-grade glioma (astrocytoma). Frozen section and cytologic preparations performed at [REDACTED] and results reported to the Physician of Record. [REDACTED]

[REDACTED]

GROSS DESCRIPTION

A. Brain, excision biopsy - [REDACTED]
Received fresh from the operating room, labeled with the patient's name and medical record number, is an approximately 1.1 x 0.6 x 0.5 cm aggregate of tan-pink, glistening, soft tissue for intraoperative consultation. Representative tissue was utilized for frozen section and cytologic preparations.
Sections: A1 Remnant of the frozen section; A2 Un-sampled tissue, entirely submitted

[REDACTED]

MICROSCOPIC DESCRIPTION

Sections show small fragments of a high-grade glioma showing mostly oval to angular nuclei. Frequent abnormal mitotic figures are present. Microvascular hypertrophy and borderline microvascular proliferation are noted. Early tumor cell palisading without frank necrosis is distinct. An immunostain for p53 highlights The Ki-67 labeling index is approximately 20%.

ICD-9(s):

239.6 239.6

[REDACTED]

Histo Data

Part A: Brain, excision biopsy

Taken:	Received:	
Stain/cnt	Block	Ordered
FS H/E x 1	1	[REDACTED]
H/E x 1	1	[REDACTED]
TPS H/E x 1	1	[REDACTED]
H/E x 1	2	[REDACTED]
MGMT x 1	2	[REDACTED]
MIB1-DA x 1	2	[REDACTED]
P53D07 x 1	2	[REDACTED]

*** End of Report ***

[REDACTED]

Source: NCI Genomic Data Commons file 7bc2bede-30b2-4ba3-bdf4-f737b29fa2dc (TCGA-06-0879.F75C6170-1411-46B6-848F-B46007F2A656.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).